Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8CA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8CA-01A (Primary Tumor).

[page 1 of 3]
Supr Path Final Report

Temporary Copy

Page 1 of 2

Case

Collected

Onsite by

ACCESSION

Submitting Physician

Clinical History

Left frontal lobe mass

Diagnosis

1. "LEFT FRONTAL TUMOR", RESECTION:
- OLIGODENDROGLIOMA, WHO GRADE II
2. "LEFT FRONTAL TUMOR", RESECTION:
- OLIGODENDROGLIOMA, WHO GRADE II

ICD-O-3
Oligodendroglioma, grade II
9450/3
Site ^{C6E} Brain, supratentorial NOS
path C71.2
Brain, frontal lobe C71.2
W 11/27/13

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

electronic signature

For questions regarding this case, call

Frozen Section Diagnosis

Frozen section diagnosis per

1FA: "Low grade infiltrating glioma"

Gross Description

This case has two parts, each of which is received labeled with the patient's name and medical record number.

Specimen one is received fresh for intraoperative frozen section labeled "#1 left frontal tumor", and consists of a 2.5 x 1.9 x 0.6 cm aggregate of tan-pink, irregular soft tissue fragments. Touch preps are performed and approximately half of the specimen is submitted for frozen section and subsequently for permanents in cassette 1FA. The remainder of the specimen is entirely submitted in cassette 1A.

Specimen two is received in formalin labeled "left frontal tumor", and consists of a 4.0 x 3.1 x 1.4 cm aggregate of tan-white, faintly hemorrhagic brain matter. The specimen is entirely submitted in cassettes 2A-2C.

Microscopic Examination

Performed.

The frozen section diagnosis is confirmed on permanent sections.

Synoptic Report

College of American Pathologists (CAP) Cancer Protocol

[page 2 of 3]
Sure Path Final Report

Temporary Copy

Page 2 of 2

Case

Collection

Organization

Patient

Location

Surgical Pathology Cancer Case Summary (Checklist)

Protocol effective date:

History of Previous Tumor/ Familial Syndrome
Not specified

Specimen Type/Procedure
Resection

Specimen Handling
Squash/smear/touch preparation
Frozen section
Unfrozen for routine permanent paraffin sections

Specimen Size
Greatest dimension: 4.0 cm

Laterality
Left

Tumor Site
Brain/cerebrum
Frontal

Histologic Type and Grade (applicable World Health
Organization [WHO] classification and grade)
Oligodendroglioma (WHO grade II)

Histologic Grade (WHO histologic grade)
WHO grade II

Ancillary Studies
Molecular genetic studies:
1p FISH - pending
19q FISH - pending

Additional Pathological Findings
None

[page 3 of 3]
Addendum Report

Temporary Copy

Page 1 of 1

Case:

Collected:

Ordered by:

Patient:

ID:

Location:

ACCESSION**Addendum Discussion**

This addendum is issued to report the results of 1p/19q FISH on the patient's previously reported oligodendroglioma.

Fluorescence in situ hybridization (FISH) analysis for deletions of 1p and/or 19q are performed on sections from block "2C".

Calculated 1p/1q ratio = 0.50 (< 0.74 is deleted)

Calculated 19q/19p ratio = 0.56 (< 0.88 is deleted)

The results are interpreted as deleted for 1p and 19q. The results are interpreted as deleted for 1p and 19q. This assay was read by

A result of a deleted 1p and 19q suggests a favorable prognosis.

Analyte Specific Reagents (ASR) are used in many laboratory tests necessary for standard medical care and generally do not require U. S. Food and Drug Administration (FDA) approval or clearance. This test was developed and its performance characteristics determined by It has not been approved or cleared by the U. S. Food and Drug Administration. This test should not be regarded as investigational or for research use.

Appropriate controls were performed at appropriately.

and stain

I certify that I personally conducted the diagnostic evaluation on the above specimen(s) and have rendered the above diagnosis(es):

electronic signature

HIVAA Discrepancy		/
Case is (reim):		

Source: NCI Genomic Data Commons file d6103a26-f884-4f2a-83e4-c09884777454 (TCGA-VM-A8CA.44E81259-80C6-4665-95DE-6D114AEE7761.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).